Somatic mutation profile of tumor specimen PCProject_0683_T2_WES (aliquot PCProject_0683_T2_WES_1) from CMI case PCProject_0683, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.1 years (22,677 days).
Specimen PCProject_0683_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abb97aeb-7c27-40df-8661-068661c08f4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0683_SALIVA (DNA), aliquot PCProject_0683_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ced28e8-e5ee-4ce8-badf-bf6d44f5c065

The open-access MAF lists 107 somatic variants for this specimen: 78 protein-altering or splice-affecting, 12 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 12, Intron 6, Nonsense Mutation 4, RNA 4, 3'UTR 3, Frame Shift Del 3, Splice Site 3, 5'UTR 2, In Frame Del 2, 3'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 49/471 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PRPH2 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 49/361 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs61755783, CM951116; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABHD11 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 65/503 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.106); catalogued as rs147198994, COSV56105232; called by muse, mutect2, varscan2
- ACTL6B | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as rs556388048; called by muse, mutect2
- APOBEC3C | c.268T>G p.W90G | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs777726652; called by muse, mutect2, varscan2
- BEND6 | c.172G>C p.D58H | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.478); catalogued as COSV100876975; called by muse, mutect2, varscan2
- BRAT1 | c.1691G>A p.S564N | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs773268982, COSV61395427; ClinVar: uncertain significance; called by muse, mutect2
- CRACD | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1197577741, COSV99073091; called by muse, mutect2
- DNAJB13 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.178); catalogued as COSV60269808; called by muse, mutect2
- FMN1 | c.4229G>C p.R1410P (on ENST00000616417 / NM_001277313.2; = p.R1187P on NM_001103184.4) | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100568233; called by muse, mutect2
- GKN2 | c.435T>G p.H145Q | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV61031403; called by muse, mutect2
- GUCA1A | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs769174329, COSV50003459; called by muse, mutect2, varscan2
- NKG7 | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.133); catalogued as COSV52467816; called by muse, mutect2, varscan2
- PCK1 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs370747699; called by muse, mutect2, varscan2
- PHLDB1 | c.1523C>T p.T508M | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.732); catalogued as rs535635967; called by muse, mutect2, varscan2
- PRDM9 | c.1014G>C p.Q338H | Missense Mutation (SNP) | VAF 84/522 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs373277404, COSV57013925; called by muse, mutect2, varscan2
- PRPF4 | c.122G>A p.R41H (on ENST00000374198 / NM_001322267.2; = p.R42H on NM_004697.5) | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs1299420214, COSV100950717; called by muse, mutect2, varscan2
- SP140 | c.1643G>A p.R548K | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as rs376571047; called by muse, mutect2, varscan2
- SULF1 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs758690728, COSV52674097; called by muse, mutect2
- TACR2 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 39/424 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs200789724, COSV100964814; called by muse, mutect2
- TMC2 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 75/401 reads (19%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1035668319, COSV62649544; called by muse, mutect2, varscan2
- UBE2E2 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 48/342 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.735); catalogued as rs777221152, COSV59980849; called by muse, mutect2, varscan2
- WNT6 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 94/464 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199916860; called by muse, mutect2, varscan2
- ZNF280B | c.1429G>C p.E477Q | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs759903725; called by muse, mutect2
- ZNF479 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 45/355 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.421); catalogued as COSV58641681; called by muse, mutect2, varscan2
- ACTR10 | c.957G>T p.L319F | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ADA | c.333A>C p.K111N | Missense Mutation (SNP) | VAF 67/478 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- ADAMTS8 | c.2525C>T p.S842F | Missense Mutation (SNP) | VAF 33/333 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- AKNAD1 | c.650A>C p.K217T | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- AMPD2 | c.2428G>T p.E810* | Nonsense Mutation (SNP) | VAF 42/454 reads (9%) | called by muse, mutect2
- ANKRD31 | c.3250G>T p.V1084F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ANPEP | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- APOL2 | c.984T>A p.H328Q | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.036); called by muse, varscan2
- ASPM | c.4650A>T p.R1550S | Missense Mutation (SNP) | VAF 28/526 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.148); called by muse, mutect2
- BEND6 | c.173A>T p.D58V | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- CACNA1D | c.4771del p.Q1591Kfs*11 (on ENST00000350061 / NM_001128840.3; = p.Q1611Kfs*11 on NM_000720.4) | Frame Shift Del (DEL) | VAF 40/325 reads (12%) | called by mutect2, pindel, varscan2
- CCNDBP1 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 25/285 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CPB1 | c.1174T>A p.S392T | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.419); called by muse, mutect2
- CRB1 | c.780A>T p.E260D | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- DGKA | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- EXTL2 | c.241A>T p.K81* | Nonsense Mutation (SNP) | VAF 15/118 reads (13%) | called by muse, mutect2, varscan2
- FRMPD1 | c.40G>C p.A14P | Missense Mutation (SNP) | VAF 25/290 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- GPR4 | c.462C>A p.F154L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GRM3 | c.671A>C p.E224A | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTRA2 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); called by muse, mutect2
- INTS12 | c.863G>C p.S288T | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.98); called by muse, mutect2
- KRTAP10-3 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 45/350 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPK6 | c.700+1G>C p.X234_splice | Splice Site (SNP) | VAF 18/308 reads (6%) | called by muse, mutect2
- MFSD12 | c.512A>T p.Y171F | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); called by muse, mutect2
- MORC1 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MSLNL | c.250_262del p.L84Pfs*36 | Frame Shift Del (DEL) | VAF 19/170 reads (11%) | called by mutect2, pindel
- MSN | c.10dup p.T4Nfs*28 | Frame Shift Ins (INS) | VAF 40/171 reads (23%) | called by mutect2, pindel, varscan2
- MYLK | c.3620A>T p.K1207M | Missense Mutation (SNP) | VAF 32/331 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- NBPF12 | c.2731T>C p.Y911H | Missense Mutation (SNP) | VAF 103/974 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NPAT | c.3591T>G p.S1197R | Missense Mutation (SNP) | VAF 44/404 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OBSCN | c.13795G>C p.V4599L | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); called by muse, mutect2
- OOSP2 | c.17T>A p.L6* | Nonsense Mutation (SNP) | VAF 17/214 reads (8%) | called by muse, mutect2
- OR1Q1 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- OR5M1 | c.29C>A p.T10K | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- PAICS | c.467T>C p.L156P | Missense Mutation (SNP) | VAF 6/30 reads (20%) | PolyPhen benign (0.003); called by muse, mutect2
- PARG | c.2364G>C p.Q788H | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PIK3CB | c.3153_3155del p.E1051_S1052delinsD | In Frame Del (DEL) | VAF 87/367 reads (24%) | called by mutect2, pindel, varscan2
- PNPLA7 | c.263G>C p.R88T | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- PODXL2 | c.1206+1G>T p.X402_splice | Splice Site (SNP) | VAF 30/186 reads (16%) | called by muse, mutect2, varscan2
- PPP2R5D | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PTCH2 | c.2386T>G p.F796V | Missense Mutation (SNP) | VAF 48/530 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2
- PTEN | c.431_444del p.K144Tfs*31 | Frame Shift Del (DEL) | VAF 29/223 reads (13%) | called by mutect2, pindel
- RGMA | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 98/397 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SBSN | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 63/492 reads (13%) | called by muse, varscan2
- SERPINF2 | c.1121T>A p.V374E | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- SH3D19 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 41/342 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SPOCD1 | c.2516C>A p.P839H | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- SYNCRIP | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TDRD15 | c.2744A>G p.N915S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- TRGV5 | c.147C>G p.F49L | Missense Mutation (SNP) | VAF 44/450 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- VIRMA | c.2155_2160del p.L719_F720del | In Frame Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel
- XPO5 | c.2984-2A>C p.X995_splice | Splice Site (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2, varscan2
- ZNF16 | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- ADGRG2 | c.1830C>A p.G610= (on ENST00000379869 / NM_001079858.3; = p.G607= on NM_005756.4) | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2
- ANAPC5 | c.966C>G p.L322= | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- CACNA1I | c.1434G>C p.G478= | Silent (SNP) | VAF 5/50 reads (10%) | called by muse, varscan2
- DNAH17 | c.7389G>A p.V2463= | Silent (SNP) | VAF 20/204 reads (10%) | catalogued as rs746976750; called by muse, mutect2, varscan2
- IQSEC3 | c.1329C>A p.A443= (on ENST00000538872 / NM_001170738.2; = p.A140= on NM_015232.1) | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV58285895; called by muse, mutect2, varscan2
- KRTAP8-1 | c.78C>T p.S26= | Silent (SNP) | VAF 32/375 reads (9%) | catalogued as rs1359494465, COSV100297813, COSV100297855; called by muse, mutect2
- MC3R | c.879C>T p.V293= | Silent (SNP) | VAF 53/362 reads (15%) | called by muse, mutect2, varscan2
- PAK6 | c.1020C>G p.G340= | Silent (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- PCDHB2 | c.1362C>A p.T454= | Silent (SNP) | VAF 116/1210 reads (10%) | called by muse, varscan2
- RYR1 | c.7182C>T p.G2394= | Silent (SNP) | VAF 33/201 reads (16%) | called by muse, mutect2, varscan2
- SPDEF | c.231C>A p.A77= | Silent (SNP) | VAF 31/206 reads (15%) | called by muse, mutect2, varscan2
- ZNF638 | c.4776T>G p.V1592= | Silent (SNP) | VAF 18/184 reads (10%) | called by muse, mutect2
- ANXA2P2 | n.202_207del | RNA (DEL) | VAF 28/201 reads (14%) | called by mutect2, pindel, varscan2
- CACNA1A | c.6322-16del | Intron (DEL) | VAF 30/247 reads (12%) | called by mutect2, pindel, varscan2
- CDADC1 | c.431-1588C>G | Intron (SNP) | VAF 12/174 reads (7%) | catalogued as COSV51914147; called by muse, mutect2
- CEP295 | chr11:93733531 T>A | 3'Flank (SNP) | VAF 13/129 reads (10%) | called by muse, mutect2, varscan2
- CHIT1 | c.*496T>C | 3'UTR (SNP) | VAF 31/294 reads (11%) | catalogued as rs893036334; called by muse, mutect2, varscan2
- CNTN6 | c.-405T>C | 5'UTR (SNP) | VAF 17/129 reads (13%) | called by muse, mutect2, varscan2
- FOXP2 | c.*808G>A | 3'UTR (SNP) | VAF 10/128 reads (8%) | catalogued as rs1299921667; called by muse, mutect2
- HNRNPA3P1 | n.280C>T | RNA (SNP) | VAF 19/111 reads (17%) | catalogued as rs564794889; called by muse, mutect2
- LINC01517 | n.216A>C | RNA (SNP) | VAF 27/170 reads (16%) | called by muse, mutect2, varscan2
- MID1 | c.757-5839_757-5830del | Intron (DEL) | VAF 22/88 reads (25%) | called by mutect2, pindel
- MTND6P20 | chr8:46841119 G>T | 3'Flank (SNP) | VAF 19/156 reads (12%) | called by muse, varscan2
- NEDD4L | c.2427-49C>G | Intron (SNP) | VAF 22/220 reads (10%) | called by muse, mutect2, varscan2
- OFCC1 | n.285C>T | RNA (SNP) | VAF 16/128 reads (13%) | catalogued as rs889790147; called by muse, mutect2, varscan2
- PAX4 | c.*23C>T | 3'UTR (SNP) | VAF 19/407 reads (5%) | called by muse, mutect2
- TFR2 | c.614+15G>T | Intron (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- TRNAU1AP | c.-8G>T | 5'UTR (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- ZNF569 | c.-43-9931A>G | Intron (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
